CGCI case BLGSP-71-19-00521 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc52be40-6a15-4642-b4a5-343dd1c96b33

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 7.6 years (2,787 days); Year of diagnosis: 2014; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,104 days (3.0 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Bone marrow; Sites of involvement: Bone marrow / Soft tissue / Lung, NOS / Pleura.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,104 days (3.0 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD19 (Flow Cytometry): Positive.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD22 (Flow Cytometry): Positive.
- CD3 (Flow Cytometry): Negative.
- CD3 (IHC): Negative.
- CD45 (Flow Cytometry): Positive.
- CD5 (Flow Cytometry): Positive.
- CD79A (Flow Cytometry): Positive.
- HLA-DR (Flow Cytometry): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Test (Flow Cytometry): Positive; Specialized molecular test: CD11c.
- Test (Flow Cytometry): Positive; Specialized molecular test: CD123.
- Test (Flow Cytometry): Positive; Specialized molecular test: CD24.
- Test (Flow Cytometry): Positive; Specialized molecular test: CD38.
- Test (Flow Cytometry): Positive; Specialized molecular test: CD45RA.
- Test (Flow Cytometry): Positive; Specialized molecular test: CD9.
- Test (Flow Cytometry): Positive; Specialized molecular test: surface Ig Kappa.
- Lactate Dehydrogenase 5865 [Blood test normal range upper: 310].

Other clinical attributes
- Day 0: Weight: 28 kg; Height: 129 cm; BMI: 16.8.

Biospecimens (3 samples)
- Sample BLGSP-71-19-00521-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00521-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Cryopreserved; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00521-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Cell; Preservation method: Cryopreserved; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 4; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Soft Tissue (muscle, ligaments, subcutaneous); Extranodal involvement site: Lung; Extranodal involvement site: Pleura/Pleural Effusion.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 5865; Immunophenotypic analysis method: Flow cytometry, not otherwise specified.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD9.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD38.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD45.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD123.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunophenotypic analysis tested: CD22.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunophenotypic analysis tested: CD24.
- Tests performed, Genetic testing results, Genetic testing result 13: Immunophenotypic analysis tested: cyCD79a.
- Tests performed, Genetic testing results, Genetic testing result 14: Immunophenotypic analysis tested: sIg Kappa.
- Tests performed, Genetic testing results, Genetic testing result 15: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 16: Immunophenotypic analysis tested: CD11c.
